Somatic mutation profile of tumor specimen C3N-04100-02 (aliquot CPT0285590006) from CPTAC case C3N-04100, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 44.7 years (16,334 days).
Specimen C3N-04100-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 13d84c68-eb28-4192-a77b-e5593717d807.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-04100-31 (Blood Derived Normal), aliquot CPT0285610002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cf2dbe4e-6618-4bf2-982e-296308d9ece9

The open-access MAF lists 95 somatic variants for this specimen: 56 protein-altering or splice-affecting, 27 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 27, Intron 5, Nonsense Mutation 4, In Frame Del 2, Frame Shift Del 2, RNA 2, 3'UTR 2, Splice Site 2, 5'Flank 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCND2 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 95/208 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587777621, CM144535, CM162083, COSV54223211, COSV54225487, COSV54226876; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 97/120 reads (81%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- ARSH | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 148/176 reads (84%) | SIFT tolerated (0.53); PolyPhen benign (0.031); catalogued as rs1279616557, COSV66963800; called by muse, mutect2, varscan2
- B3GALNT2 | c.1421_1423del p.P474del | In Frame Del (DEL) | VAF 48/160 reads (30%) | catalogued as rs752758430; called by pindel, varscan2
- BABAM2 | c.859G>A p.V287M | Missense Mutation (SNP) | VAF 77/152 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs748807354, COSV59621786; called by muse, mutect2, varscan2
- BSN | c.7894C>T p.R2632C | Missense Mutation (SNP) | VAF 90/188 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781389616, COSV99608185; called by muse, mutect2, varscan2
- BSND | c.64G>A p.G22S | Missense Mutation (SNP) | VAF 22/330 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145048739; called by muse, mutect2
- C4orf54 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 75/211 reads (36%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs983110665; called by muse, mutect2, varscan2
- CLEC4E | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778305486, COSV55227338; called by muse, mutect2, varscan2
- CLK2 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 45/166 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.12); catalogued as rs781186813, COSV62877322; called by muse, mutect2, varscan2
- FRMPD4 | c.572C>T p.S191L | Missense Mutation (SNP) | VAF 48/52 reads (92%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as rs1263695778; called by muse, mutect2, varscan2
- GLB1L3 | c.1229C>G p.P410R | Missense Mutation (SNP) | VAF 72/92 reads (78%) | SIFT tolerated (0.24); PolyPhen benign (0.119); catalogued as COSV101345141, COSV101345152; called by muse, mutect2, varscan2
- HNF4A | c.938C>A p.S313Y | Missense Mutation (SNP) | VAF 91/293 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100291687; called by muse, mutect2, varscan2
- HPS5 | c.1651C>T p.R551C (on ENST00000349215 / NM_181507.2; = p.R437C on NM_007216.4) | Missense Mutation (SNP) | VAF 93/125 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs576840531; called by muse, mutect2, varscan2
- IFNG | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as rs573063245, COSV57490777; called by muse, mutect2, varscan2
- IGHMBP2 | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 7/199 reads (4%) | catalogued as rs972425138, CM034524, COSV54821463; ClinVar: uncertain significance; called by muse, mutect2
- PCDH15 | c.1745C>T p.T582M | Missense Mutation (SNP) | VAF 27/179 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752608084, COSV57303490, COSV57332850; called by muse, mutect2, varscan2
- PHLDB2 | c.2353C>T p.H785Y (on ENST00000393925 / NM_001134439.2; = p.H742Y on NM_145753.2) | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.756); catalogued as rs1281832259, COSV101208621; called by muse, mutect2, varscan2
- PPFIA2 | c.3367C>T p.R1123* | Nonsense Mutation (SNP) | VAF 85/191 reads (45%) | catalogued as rs1212945301, COSV61026841; called by muse, mutect2, varscan2
- PRDM9 | c.1856G>A p.R619Q | Missense Mutation (SNP) | VAF 176/474 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1410684355, COSV99690299; called by muse, varscan2
- RAB21 | c.126C>G p.N42K | Missense Mutation (SNP) | VAF 106/234 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.25); catalogued as COSV99715000; called by muse, varscan2
- RP1 | c.3061G>A p.V1021I | Missense Mutation (SNP) | VAF 88/229 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.216); catalogued as rs749695036, COSV73140907; called by muse, mutect2, varscan2
- SCN7A | c.2284G>A p.V762M | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as rs376252927; called by muse, mutect2, varscan2
- SLC11A1 | c.1133C>T p.T378M | Missense Mutation (SNP) | VAF 27/225 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1032261832, COSV104373434; called by muse, mutect2, varscan2
- SLC35G6 | c.334G>A p.V112I | Missense Mutation (SNP) | VAF 232/553 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs757753838; called by muse, mutect2, varscan2
- TMEM40 | c.557C>A p.S186Y | Missense Mutation (SNP) | VAF 101/216 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53146785; called by muse, mutect2, varscan2
- TNFAIP8L3 | c.725C>T p.T242M | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs998709072; called by muse, mutect2
- UNC5D | c.2314-1G>T p.X772_splice | Splice Site (SNP) | VAF 36/72 reads (50%) | catalogued as COSV99772022; called by mutect2, varscan2
- USP6 | c.3443C>T p.S1148L | Missense Mutation (SNP) | VAF 72/176 reads (41%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.031); catalogued as rs375831983; called by muse, mutect2, varscan2
- ZFAND2A | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs748607914; called by muse, mutect2
- ZMYND8 | c.409G>A p.E137K (on ENST00000311275 / NM_001363741.2; = p.E157K on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/293 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53695193, COSV53695279; called by muse, mutect2, varscan2
- ZNF716 | c.1013C>A p.T338N | Missense Mutation (SNP) | VAF 116/435 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as COSV70782448; called by muse, mutect2, varscan2
- ADAMTS3 | c.1348_1349del p.I450Pfs*4 | Frame Shift Del (DEL) | VAF 62/228 reads (27%) | called by pindel, varscan2
- ARMH4 | c.2109A>C p.K703N | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ASB14 | c.671C>A p.A224D (on ENST00000389601; = p.A223D on NM_001142733.3) | Missense Mutation (SNP) | VAF 145/316 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCAR2 | c.2333-2A>G p.X778_splice | Splice Site (SNP) | VAF 47/127 reads (37%) | called by muse, mutect2, varscan2
- CHD5 | c.480C>G p.N160K | Missense Mutation (SNP) | VAF 90/195 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CIT | c.2094G>C p.E698D | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CROCC | c.388G>T p.E130* | Nonsense Mutation (SNP) | VAF 50/122 reads (41%) | called by muse, mutect2, varscan2
- DKK2 | c.666del p.H223Mfs*41 | Frame Shift Del (DEL) | VAF 180/455 reads (40%) | called by mutect2, pindel, varscan2
- DPH1 | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 95/261 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- EFS | c.373G>T p.D125Y | Missense Mutation (SNP) | VAF 137/278 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EPHA7 | c.1945A>G p.S649G | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.656); called by muse, varscan2
- FIP1L1 | c.376G>A p.G126R | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- IL5RA | c.309G>C p.Q103H | Missense Mutation (SNP) | VAF 95/227 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF21A | c.1717G>A p.A573T (on ENST00000361418 / NM_001378440.1; = p.A560T on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/203 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- LSR | c.217G>A p.V73I | Missense Mutation (SNP) | VAF 87/400 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MARCHF3 | c.299G>T p.C100F | Missense Mutation (SNP) | VAF 143/343 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MUC16 | c.18437C>G p.P6146R | Missense Mutation (SNP) | VAF 107/370 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- PLEKHH2 | c.2014C>A p.P672T | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ROCK1 | c.2779A>G p.N927D | Missense Mutation (SNP) | VAF 81/163 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- SERINC4 | c.559_579del p.C187_I193del | In Frame Del (DEL) | VAF 40/220 reads (18%) | called by mutect2, pindel
- ST3GAL3 | c.640G>A p.V214M (on ENST00000361392 / NM_174964.4; = p.V199M on NM_006279.5) | Missense Mutation (SNP) | VAF 171/380 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYNE2 | c.6581A>C p.D2194A | Missense Mutation (SNP) | VAF 155/316 reads (49%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- UGT2B7 | c.787A>T p.N263Y | Missense Mutation (SNP) | VAF 83/185 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- ZNF426 | c.1063G>A p.V355I | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- ABCB4 | c.303G>A p.S101= | Silent (SNP) | VAF 42/254 reads (17%) | catalogued as rs886044650, COSV55943119; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD163L1 | c.468G>A p.R156= | Silent (SNP) | VAF 15/41 reads (37%) | called by muse, mutect2, varscan2
- COL20A1 | c.2947A>C p.R983= | Silent (SNP) | VAF 19/412 reads (5%) | called by muse, mutect2
- DOC2B | c.891C>T p.D297= | Silent (SNP) | VAF 63/164 reads (38%) | catalogued as rs774378997, COSV59095393, COSV59095689; called by muse, mutect2, varscan2
- DPYSL2 | c.1530C>T p.P510= | Silent (SNP) | VAF 90/234 reads (38%) | called by muse, mutect2, varscan2
- DSCAML1 | c.3882C>G p.G1294= (on ENST00000321322; = p.G1234= on NM_020693.4) | Silent (SNP) | VAF 42/59 reads (71%) | called by muse, mutect2, varscan2
- FAM71E2 | c.2538G>A p.A846= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs949499154, COSV58484511; called by muse, mutect2, varscan2
- GALNS | c.825G>A p.L275= | Silent (SNP) | VAF 186/423 reads (44%) | called by muse, mutect2, varscan2
- HECW2 | c.453A>T p.R151= | Silent (SNP) | VAF 57/161 reads (35%) | called by muse, mutect2, varscan2
- HIVEP3 | c.444C>T p.H148= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs753892817; called by muse, mutect2, varscan2
- LMOD1 | c.1110A>C p.R370= | Silent (SNP) | VAF 204/411 reads (50%) | called by muse, mutect2, varscan2
- NAA40 | c.507G>A p.K169= | Silent (SNP) | VAF 43/55 reads (78%) | called by muse, mutect2, varscan2
- OR2T27 | c.366C>G p.R122= | Silent (SNP) | VAF 85/285 reads (30%) | catalogued as rs140994206; called by muse, varscan2
- PCDHB10 | c.1809G>A p.S603= | Silent (SNP) | VAF 92/471 reads (20%) | catalogued as COSV99505003; called by muse, mutect2, varscan2
- PDILT | c.1221C>T p.D407= | Silent (SNP) | VAF 73/143 reads (51%) | catalogued as rs774036878, COSV56701690; called by muse, mutect2, varscan2
- RAI1 | c.3885G>A p.P1295= | Silent (SNP) | VAF 29/60 reads (48%) | catalogued as rs146259338, COSV55389126; called by muse, mutect2, varscan2
- SCN9A | c.4974C>T p.Y1658= (on ENST00000303354; = p.Y1647= on NM_002977.3) | Silent (SNP) | VAF 70/120 reads (58%) | catalogued as rs757858235, COSV57600994; ClinVar: likely benign; called by muse, mutect2, varscan2
- SHTN1 | c.1599G>A p.P533= | Silent (SNP) | VAF 50/60 reads (83%) | catalogued as rs371326209, COSV53382410; called by muse, mutect2, varscan2
- SIRPB2 | c.33G>A p.L11= | Silent (SNP) | VAF 55/163 reads (34%) | called by muse, mutect2, varscan2
- SLC23A1 | c.297C>T p.T99= | Silent (SNP) | VAF 54/123 reads (44%) | catalogued as rs749185244, COSV100811956; called by muse, mutect2, varscan2
- SNTG2 | c.1206C>T p.N402= | Silent (SNP) | VAF 166/359 reads (46%) | catalogued as rs371202003; called by muse, mutect2, varscan2
- TENM3 | c.4722A>T p.P1574= | Silent (SNP) | VAF 55/127 reads (43%) | called by muse, mutect2, varscan2
- TSSK4 | c.786C>T p.T262= | Silent (SNP) | VAF 40/76 reads (53%) | called by muse, mutect2, varscan2
- TTC14 | c.894G>A p.L298= | Silent (SNP) | VAF 36/84 reads (43%) | called by muse, mutect2, varscan2
- TTN | c.36597C>T p.N12199= (on ENST00000591111; = p.N4775= on NM_003319.4) | Silent (SNP) | VAF 26/65 reads (40%) | catalogued as COSV59950197; called by muse, mutect2, varscan2
- UMOD | c.1029G>A p.S343= | Silent (SNP) | VAF 226/515 reads (44%) | catalogued as rs375846119, COSV56773517, COSV56778852; called by muse, mutect2, varscan2
- VIT | c.369G>A p.S123= | Silent (SNP) | VAF 59/141 reads (42%) | called by muse, mutect2, varscan2
- AC024651.2 | chr15:97873957 C>T | 5'Flank (SNP) | VAF 35/73 reads (48%) | catalogued as rs1037337776; called by muse, mutect2
- C5orf17 | n.326A>T | RNA (SNP) | VAF 9/37 reads (24%) | catalogued as rs1236030583; called by muse, mutect2, varscan2
- CLEC4A | c.299-771G>A | Intron (SNP) | VAF 41/82 reads (50%) | called by muse, mutect2, varscan2
- CPLANE1 | c.*2144G>A | 3'UTR (SNP) | VAF 13/197 reads (7%) | catalogued as rs1048318459, COSV57061430; called by muse, mutect2
- CT45A3 | c.*47G>A | 3'UTR (SNP) | VAF 36/534 reads (7%) | catalogued as rs1159873872; called by muse, mutect2
- EYS | c.1767-6545C>T | Intron (SNP) | VAF 111/394 reads (28%) | catalogued as rs773286608, COSV65458460; called by muse, mutect2, varscan2
- FOXP1 | c.1723-35T>C | Intron (SNP) | VAF 62/167 reads (37%) | called by muse, mutect2, varscan2
- NANOS3 | chr19:13875002 G>A | 5'Flank (SNP) | VAF 20/60 reads (33%) | called by muse, mutect2, varscan2
- SATB1 | c.1779+712G>A | Intron (SNP) | VAF 165/403 reads (41%) | called by muse, mutect2, varscan2
- SF1 | c.236+16del | Intron (DEL) | VAF 83/130 reads (64%) | called by mutect2, pindel, varscan2
- TAAR3P | n.247A>G | RNA (SNP) | VAF 54/116 reads (47%) | catalogued as rs1475993458; called by muse, mutect2, varscan2
- TRIQK | chr8:92884915 C>A | 3'Flank (SNP) | VAF 14/438 reads (3%) | called by muse, mutect2
